Somatic mutation profile of tumor specimen TCGA-EL-A3D5-01A (aliquot TCGA-EL-A3D5-01A-22D-A202-08) from TCGA case TCGA-EL-A3D5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 44.4 years (16,217 days).
Specimen TCGA-EL-A3D5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e20f8ead-7cbe-4a21-a74f-363b5682fff7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3D5-10A (Blood Derived Normal), aliquot TCGA-EL-A3D5-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6169cc24-a292-47a3-b223-1a4812d4bcc2

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Frame Shift Del 3, Splice Site 2, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 126/371 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- ABCB11 | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55603324; called by muse, mutect2, varscan2
- NCAN | c.3820C>T p.P1274S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs148844959; called by muse, mutect2, varscan2
- ORC2 | c.238+1G>C p.X80_splice | Splice Site (SNP) | VAF 42/146 reads (29%) | catalogued as COSV52242119; called by muse, mutect2, varscan2
- TSPYL2 | c.1238+2T>A p.X413_splice | Splice Site (SNP) | VAF 23/68 reads (34%) | catalogued as COSV60238597, COSV60238724; called by muse, mutect2, varscan2
- AMDHD1 | c.1000del p.D334Ifs*20 | Frame Shift Del (DEL) | VAF 27/109 reads (25%) | called by mutect2, pindel, varscan2
- DICER1 | c.243_246del p.S82Ifs*45 | Frame Shift Del (DEL) | VAF 47/188 reads (25%) | called by mutect2, pindel, varscan2
- TP53 | c.1028_1029del p.E343Afs*3 | Frame Shift Del (DEL) | VAF 21/45 reads (47%) | called by pindel, varscan2
- HOXC11 | c.537G>T p.G179= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV54534325; called by muse, mutect2, varscan2
- NPY1R | c.612G>A p.S204= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs772998084, COSV56717004; called by muse, mutect2, varscan2
- SF3B3 | c.2763A>T p.A921= | Silent (SNP) | VAF 6/151 reads (4%) | catalogued as COSV56791861; called by muse, mutect2
